Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAI7, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAI7-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 7.0 cm; tumor is present in the rete testis; no angio-invasion; the tunica albuginea and epididymis are not penetrated. The cord is not involved, including the resection margin.

Date of procurement (= date of orchidectomy):

ICD C3
Seminoma NOS 9061/3
Site: R. Testis NOS 9029
3/7/13

pathologist

professor of pathology

Criteria	W 1/18/14	Yes	No

Source: NCI Genomic Data Commons file 4b53091e-9fb3-4379-a61f-72b268666e86 (TCGA-2G-AAI7-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).